Somatic mutation profile of tumor specimen C3L-01043-01 (aliquot CPT0127420006) from CPTAC case C3L-01043, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,551 days).
Specimen C3L-01043-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cb0b3b5-1acd-4093-aaed-8ff03df54bef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01043-31 (Blood Derived Normal), aliquot CPT0128550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bcd4695-1535-4d6a-85b1-e1a882b8dbc1

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, 5'UTR 2, RNA 2, Splice Site 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD31 | c.5350C>A p.P1784T | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1404436317; called by muse, mutect2, varscan2
- ARHGAP45 | c.2818C>T p.R940W | Missense Mutation (SNP) | VAF 99/459 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768714766; called by muse, mutect2, varscan2
- CCDC105 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 70/249 reads (28%) | catalogued as rs372493151; called by muse, mutect2, varscan2
- CHD8 | c.3562C>T p.R1188* (on ENST00000646647 / NM_001170629.2; = p.R909* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 53/153 reads (35%) | catalogued as rs1555314911; called by muse, mutect2, varscan2
- DDX43 | c.318A>T p.E106D | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs962351288; called by muse, mutect2, varscan2
- FAT4 | c.10252G>A p.G3418R | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58710195; called by muse, mutect2, varscan2
- GRIN3A | c.2095A>G p.S699G | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775690934; called by muse, mutect2, varscan2
- KCNB2 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1422039688, COSV73049971; called by muse, mutect2, varscan2
- KRT25 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755553881; called by muse, mutect2, varscan2
- MRGPRD | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs758400192, COSV58423045; called by muse, mutect2, varscan2
- NYAP2 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56006346; called by muse, mutect2, varscan2
- OR7C1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs772802995, COSV50183672; called by muse, mutect2, varscan2
- PAPPA2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 72/263 reads (27%) | catalogued as rs557625059, COSV100867139, COSV62772170; called by muse, mutect2, varscan2
- PTEN | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as CD992557, COSV64310805; called by muse, mutect2, varscan2
- RYR3 | c.10694C>T p.T3565M (on ENST00000389232; = p.T3566M on NM_001036.6) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as rs373357553; called by muse, mutect2, varscan2
- TEX15 | c.5404G>A p.D1802N (on ENST00000256246; = p.D2185N on NM_001350162.2) | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as rs754802025, COSV56341671, COSV56345448; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs151254233; called by muse, mutect2, varscan2
- XCR1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757552327, COSV100499258, COSV58568820; called by muse, mutect2, varscan2
- ABCG4 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS17 | c.2516A>G p.N839S | Missense Mutation (SNP) | VAF 139/510 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- AL136295.1 | c.119dup p.L40Ffs*20 | Frame Shift Ins (INS) | VAF 36/163 reads (22%) | called by mutect2, pindel, varscan2
- CEP290 | c.1266G>C p.E422D | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLEC4C | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCC | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 15/493 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.113); called by muse, mutect2
- DDC | c.201+1G>A p.X67_splice | Splice Site (SNP) | VAF 130/522 reads (25%) | called by muse, mutect2, varscan2
- DOCK6 | c.2731G>T p.E911* | Nonsense Mutation (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- ERCC3 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IZUMO1R | c.304A>T p.N102Y | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH2A | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR4M1 | c.236del p.P79Lfs*5 | Frame Shift Del (DEL) | VAF 56/369 reads (15%) | called by mutect2, pindel, varscan2
- TIGD5 | c.1403del p.V468Gfs*128 | Frame Shift Del (DEL) | VAF 113/448 reads (25%) | called by mutect2, pindel, varscan2
- USP34 | c.8531T>C p.V2844A | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- VARS1 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VASH2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XIRP2 | c.1881A>T p.K627N (on ENST00000628543; = p.K802N on NM_152381.6) | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- CACNG5 | c.360C>T p.I120= | Silent (SNP) | VAF 47/236 reads (20%) | catalogued as rs368963780; called by muse, mutect2, varscan2
- DNAJC5B | c.63C>T p.Y21= | Silent (SNP) | VAF 73/287 reads (25%) | catalogued as rs764193345, COSV52535529; called by muse, mutect2, varscan2
- ERVW-1 | c.1093C>T p.L365= | Silent (SNP) | VAF 92/464 reads (20%) | called by muse, varscan2
- FUT5 | c.420G>A p.P140= | Silent (SNP) | VAF 106/358 reads (30%) | catalogued as rs201760120, COSV53136637; called by muse, mutect2, varscan2
- HHATL | c.783C>T p.V261= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as rs1250869581; called by muse, mutect2, varscan2
- NTRK2 | c.1635C>T p.G545= (on ENST00000323115 / NM_001369534.1; = p.G561= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/512 reads (21%) | catalogued as rs78346623; called by muse, mutect2, varscan2
- PCDHA4 | c.1752G>A p.S584= | Silent (SNP) | VAF 123/361 reads (34%) | catalogued as rs1168359860, COSV63539750; called by muse, mutect2, varscan2
- RASGRF2 | c.2049C>T p.S683= | Silent (SNP) | VAF 90/316 reads (28%) | catalogued as rs142772897; called by muse, mutect2, varscan2
- AL133373.3 | n.812C>G | RNA (SNP) | VAF 103/407 reads (25%) | called by muse, mutect2, varscan2
- CPNE6 | c.-109T>C | 5'UTR (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- LINC02876 | n.420C>T | RNA (SNP) | VAF 32/117 reads (27%) | catalogued as rs746872255; called by muse, mutect2
- ST8SIA3 | c.-132G>A | 5'UTR (SNP) | VAF 17/55 reads (31%) | catalogued as rs1448477746; called by muse, mutect2, varscan2
- UBQLN1 | chr9:83712900 G>A | 5'Flank (SNP) | VAF 95/327 reads (29%) | called by muse, mutect2, varscan2
